Somatic mutation profile of tumor specimen HTMCP-03-06-02361-01A (aliquot HTMCP-03-06-02361-01A-01D-9392) from CGCI case HTMCP-03-06-02361, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.1 years (21,227 days).
Specimen HTMCP-03-06-02361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee4ae6cc-1466-4539-9521-a0fc5bf83e59.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02361-10A (Blood Derived Normal), aliquot HTMCP-03-06-02361-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e046842-4e7b-440d-a65d-6c20739a22a3

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Nonsense Mutation 3, Splice Region 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 23/188 reads (12%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ACACA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs758519292; called by muse, mutect2, varscan2
- CFAP47 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 38/202 reads (19%) | catalogued as COSV52893468; called by muse, mutect2, varscan2
- COL7A1 | c.5720G>T p.G1907V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095160; called by muse, varscan2
- DOCK5 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99377766; called by muse, mutect2, varscan2
- DYSF | c.6058C>T p.R2020C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370286628, COSV99244446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.623); catalogued as rs774549333, COSV100668510, COSV62567072; called by muse, mutect2, varscan2
- EIF4A2 | c.687G>C p.M229I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV56215365; called by muse, mutect2, varscan2
- FLG | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.417); catalogued as CM1513736, COSV64249588; called by muse, mutect2, varscan2
- HOXC13 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747385249, COSV54498111; called by muse, mutect2, varscan2
- MYH8 | c.5230G>A p.V1744M | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs746549585; called by muse, mutect2, varscan2
- OCRL | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV63980922; called by muse, mutect2, varscan2
- OGFR | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); catalogued as rs1317077487; called by muse, mutect2, varscan2
- PCDH17 | c.3451G>C p.G1151R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64976762; called by mutect2, varscan2
- SHROOM2 | c.4202C>T p.T1401M | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs975946898, COSV101098338; called by muse, mutect2, varscan2
- SLC39A6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV52372018; called by muse, mutect2
- STARD9 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs529751938, COSV51907019; called by muse, mutect2, varscan2
- TARS2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs780461008, COSV64696186; called by muse, mutect2, varscan2
- ZNF175 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs771299652, COSV51794845; called by muse, mutect2, varscan2
- ZNF521 | c.3119C>T p.T1040M | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1241017627; called by muse, mutect2, varscan2
- ASH1L | c.2584G>C p.E862Q | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- EPB41L1 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERCC6L | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD3 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GREB1 | c.4726G>A p.V1576I | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- GUCY2C | c.2875+5G>C | Splice Region (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- HSPG2 | c.5548C>T p.Q1850* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- MAGI1 | c.4169G>C p.G1390A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCKAP5 | c.3349A>T p.S1117C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PHACTR4 | c.1936G>A p.E646K (on ENST00000373839 / NM_001350159.2; = p.E656K on NM_023923.4) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- RGPD4 | c.3230G>T p.W1077L | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRRM2 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- SYN1 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2
- TRUB2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- UTP20 | c.3406C>G p.Q1136E | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- VSIG10L | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF407 | c.4296C>A p.H1432Q | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF571 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ZNF587 | c.164-3C>T | Splice Region (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- ZNF91 | c.3429T>A p.F1143L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADGRB2 | c.423G>A p.L141= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs771963142, COSV57078440; called by muse, mutect2, varscan2
- COL7A1 | c.5520G>A p.L1840= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1001076813; called by muse, mutect2, varscan2
- GOLGB1 | c.4548C>T p.L1516= | Silent (SNP) | VAF 136/277 reads (49%) | catalogued as rs1158143247; called by muse, mutect2, varscan2
- KCNV1 | c.483G>C p.L161= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV99819266; called by muse, mutect2, varscan2
- MYO3B | c.111C>T p.T37= | Silent (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- NBPF12 | c.367T>C p.L123= | Silent (SNP) | VAF 29/359 reads (8%) | called by muse, mutect2, varscan2
- NEB | c.6390C>T p.A2130= | Silent (SNP) | VAF 94/182 reads (52%) | catalogued as rs974601635; called by muse, mutect2, varscan2
- PCDH9 | c.1101C>T p.I367= | Silent (SNP) | VAF 41/293 reads (14%) | called by muse, mutect2, varscan2
- POM121L12 | c.258C>T p.P86= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs376672272; called by muse, mutect2, varscan2
- RBFOX1 | c.429C>T p.I143= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100304003, COSV60958459; called by muse, mutect2, varscan2
- SLC13A3 | c.1023C>T p.A341= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1180074032; called by muse, mutect2, varscan2
- SLIT3 | c.3405C>T p.I1135= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs756813959; called by muse, varscan2
- TENM3 | c.7710G>A p.A2570= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs941971946, COSV101305174; called by muse, mutect2, varscan2
- UBE4B | c.3693G>A p.E1231= (on ENST00000343090 / NM_001105562.3; = p.E1102= on NM_006048.5) | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- VPS13A | c.5619G>A p.K1873= | Silent (SNP) | VAF 51/351 reads (15%) | called by muse, mutect2, varscan2
- ZNF407 | c.345C>G p.T115= | Silent (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2, varscan2
- ZNF670 | c.96G>A p.V32= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- CNGA3 | c.-6G>A | 5'UTR (SNP) | VAF 116/237 reads (49%) | catalogued as rs764493075; called by muse, mutect2, varscan2
